Somatic mutation profile of tumor specimen TCGA-19-4068-01A (aliquot TCGA-19-4068-01A-01D-1353-08) from TCGA case TCGA-19-4068, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 68.3 years (24,945 days).
Specimen TCGA-19-4068-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2361b02b-e34e-4fbf-98a9-2d52f11fa557.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-4068-10A (Blood Derived Normal), aliquot TCGA-19-4068-10A-01D-1353-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4591111-97c2-4606-9c99-e928ec4728a3

The open-access MAF lists 63 somatic variants for this specimen: 39 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 21, Nonsense Mutation 3, Frame Shift Del 3, In Frame Del 1, 5'Flank 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAG1 | c.2210G>A p.R737H | Missense Mutation (SNP) | VAF 75/175 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs104894286, CM981696; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMDEC1 | c.347C>G p.T116R | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.38); catalogued as COSV56474379; called by muse, mutect2, varscan2
- ADGRA2 | c.2020G>A p.V674M | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs772222895, COSV59441378; called by muse, mutect2, varscan2
- AFG3L2 | c.1043G>C p.G348A | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52313011; called by muse, mutect2, varscan2
- BMP5 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1160709998, COSV63701397; called by muse, mutect2, varscan2
- CALCR | c.968C>T p.A323V (on ENST00000649521 / NM_001164737.2; = p.A307V on NM_001742.4) | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.312); catalogued as rs527875590, COSV100810692, COSV64006212; called by muse, mutect2, varscan2
- CD209 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 247/666 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as rs200282091; called by muse, mutect2, varscan2
- CDC42EP1 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs766928175, COSV50756033; called by muse, mutect2, varscan2
- CHD5 | c.4895C>T p.P1632L | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); catalogued as rs201640978, COSV52409150; called by muse, mutect2, varscan2
- DEFB131A | c.149del p.C50Lfs*10 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | catalogued as COSV58416038, COSV58416294; called by mutect2, pindel, varscan2
- DKK1 | c.668A>G p.H223R | Missense Mutation (SNP) | VAF 83/123 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746527234, COSV64760007; called by muse, mutect2, varscan2
- DPP10 | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 56/174 reads (32%) | catalogued as COSV59668525, COSV59696071; called by muse, mutect2, varscan2
- DST | c.5450A>T p.Q1817L | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99760871; called by muse, mutect2
- ERCC6L | c.110T>A p.L37Q | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV57819672; called by muse, mutect2, varscan2
- FRMPD3 | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 113/292 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs779633704, COSV99347303; called by muse, mutect2, varscan2
- GPX4 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs369712159; called by muse, mutect2, varscan2
- IGFN1 | c.1298C>T p.T433I (on ENST00000295591 / NM_001367841.1; = p.T2890I on NM_001164586.2) | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.159); catalogued as rs1558152037, COSV55169159; called by muse, mutect2, varscan2
- IMPG2 | c.1306G>C p.D436H | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV51974464; called by muse, mutect2, varscan2
- KRT18 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.045); catalogued as rs147541172; called by muse, mutect2, varscan2
- KRTAP10-2 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.152); catalogued as rs782638553, COSV59954001; called by muse, mutect2, varscan2
- KRTAP10-7 | c.1037T>G p.V346G | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV59109819; called by muse, mutect2, varscan2
- MCM3 | c.1120C>T p.R374* (on ENST00000229854 / NM_001366374.2; = p.R364* on NM_002388.6 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 37/96 reads (39%) | catalogued as rs769266579, COSV57716743; called by muse, mutect2, varscan2
- NCL | c.848A>G p.E283G | Missense Mutation (SNP) | VAF 150/396 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV59545106; called by muse, mutect2, varscan2
- OR8J3 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550603090, COSV56879225; called by muse, mutect2, varscan2
- PRSS58 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 99/473 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs138718517, COSV73488461; called by muse, mutect2, varscan2
- RORC | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59091823; called by muse, mutect2, varscan2
- RPTN | c.1888C>A p.Q630K | Missense Mutation (SNP) | VAF 121/292 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV60166541; called by muse, mutect2, varscan2
- SH3GL3 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 37/98 reads (38%) | catalogued as rs765453714, COSV61053899; called by muse, mutect2, varscan2
- SLC12A5 | c.532A>G p.T178A (on ENST00000454036 / NM_001134771.2; = p.T155A on NM_020708.5) | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54789645; called by muse, mutect2, varscan2
- SLC6A14 | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 159/383 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781955858, COSV64140822; called by muse, mutect2, varscan2
- SUSD5 | c.1538C>T p.T513M | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.732); catalogued as rs372702857; called by muse, mutect2, varscan2
- TFF2 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757931974, COSV52295740, COSV99367174; called by muse, mutect2, varscan2
- THEG | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 99/269 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs765286177, COSV61073226; called by muse, mutect2, varscan2
- THPO | c.943C>T p.R315W (on ENST00000649095 / NM_001290003.1; = p.R175W on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/235 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs746926877, COSV52615106; called by muse, mutect2, varscan2
- TRIM41 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776938769, COSV59317700; called by muse, mutect2, varscan2
- CRACR2B | c.528G>T p.E176D | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2
- F8 | c.1198del p.T400Lfs*18 | Frame Shift Del (DEL) | VAF 56/163 reads (34%) | called by mutect2, pindel, varscan2
- MYH6 | c.3324_3325del p.K1109Tfs*24 | Frame Shift Del (DEL) | VAF 210/620 reads (34%) | called by mutect2, pindel, varscan2
- SLCO6A1 | c.1079_1099del p.L360_T367delinsP | In Frame Del (DEL) | VAF 40/195 reads (21%) | called by mutect2, pindel
- ACACB | c.6180G>A p.T2060= | Silent (SNP) | VAF 48/122 reads (39%) | catalogued as rs748417042, COSV58129598; called by muse, mutect2, varscan2
- ALDH3A1 | c.1110C>T p.N370= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs374241489; called by muse, mutect2, varscan2
- ATP8B4 | c.2079C>T p.D693= | Silent (SNP) | VAF 84/206 reads (41%) | catalogued as rs781742233, COSV52710450; called by muse, mutect2, varscan2
- CD163L1 | c.4230G>A p.E1410= | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as COSV58013505; called by muse, mutect2, varscan2
- DNAI2 | c.408C>T p.D136= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs770624431, COSV56757185; called by muse, mutect2, varscan2
- DSG4 | c.1752A>G p.L584= | Silent (SNP) | VAF 47/144 reads (33%) | catalogued as COSV57389047; called by muse, mutect2, varscan2
- DYNC2H1 | c.2421C>T p.I807= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs763470063, COSV62090204; called by muse, mutect2, varscan2
- F9 | c.1026G>A p.T342= | Silent (SNP) | VAF 136/371 reads (37%) | catalogued as rs954954812, COSV54378958; ClinVar: likely benign; called by muse, mutect2, varscan2
- FZD3 | c.771G>A p.L257= | Silent (SNP) | VAF 105/286 reads (37%) | catalogued as COSV53534556; called by muse, mutect2, varscan2
- HMCN1 | c.3177C>T p.Y1059= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as rs757058220, COSV54881874; called by muse, mutect2, varscan2
- LAMB1 | c.2349C>T p.S783= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs775144042, COSV55962240, COSV55969152; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO3A | c.3870C>T p.S1290= | Silent (SNP) | VAF 76/100 reads (76%) | catalogued as COSV56321869, COSV99777807; called by muse, mutect2, varscan2
- OR5D18 | c.294C>T p.C98= | Silent (SNP) | VAF 168/447 reads (38%) | catalogued as rs147156620, COSV100450499, COSV61738187; called by muse, mutect2, varscan2
- PITPNM2 | c.2850A>G p.S950= | Silent (SNP) | VAF 2/10 reads (20%) | catalogued as COSV54898092; called by muse, mutect2
- PKHD1L1 | c.6183A>T p.G2061= | Silent (SNP) | VAF 39/86 reads (45%) | catalogued as COSV65740264; called by muse, mutect2, varscan2
- SBSPON | c.321C>T p.N107= | Silent (SNP) | VAF 103/248 reads (42%) | catalogued as rs200404302, COSV52075774, COSV99817285; called by muse, mutect2, varscan2
- SHISA5 | c.684C>T p.Y228= | Silent (SNP) | VAF 77/174 reads (44%) | catalogued as COSV56496238; called by muse, mutect2, varscan2
- SPATA31D1 | c.4068C>A p.T1356= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs749874090, COSV61194163; called by muse, mutect2, varscan2
- TMEM26 | c.942G>A p.S314= | Silent (SNP) | VAF 55/75 reads (73%) | catalogued as rs199811582; called by muse, mutect2, varscan2
- UBQLN3 | c.1429C>T p.L477= | Silent (SNP) | VAF 56/153 reads (37%) | catalogued as COSV61163428; called by muse, mutect2, varscan2
- ZMYM3 | c.2532C>A p.V844= | Silent (SNP) | VAF 63/156 reads (40%) | catalogued as COSV58736425; called by muse, mutect2, varscan2
- AL645933.1 | chr6:31463769 C>T | 5'Flank (SNP) | VAF 148/387 reads (38%) | called by muse, mutect2, varscan2
- CA10 | c.61+22787C>T | Intron (SNP) | VAF 35/96 reads (36%) | catalogued as rs771970744, COSV53364644; called by muse, mutect2, varscan2
- OR3A4P | n.699G>A | RNA (SNP) | VAF 45/145 reads (31%) | catalogued as rs141261218; called by muse, mutect2, varscan2
